Somatic mutation profile of tumor specimen TCGA-55-7724-01A (aliquot TCGA-55-7724-01A-11D-2167-08) from TCGA case TCGA-55-7724, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.4 years (27,891 days).
Specimen TCGA-55-7724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07bbadef-2815-4742-a5d4-ec8af2b9610f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7724-10A (Blood Derived Normal), aliquot TCGA-55-7724-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd460fa4-1c27-4f4f-ba40-6e0bc0857bd5

The open-access MAF lists 213 somatic variants for this specimen: 168 protein-altering or splice-affecting, 43 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 43, Nonsense Mutation 19, Splice Site 2, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- DSP | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as rs876657638, CM114455, COSV101131165; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.3764G>C p.G1255A (on ENST00000265723 / NM_018849.3; = p.G1248A on NM_000443.4) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99709584; called by muse, mutect2
- ACTR5 | c.1342A>G p.R448G | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99709859; called by muse, mutect2
- ACTRT1 | c.208T>A p.L70M | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100947490, COSV64419660; called by muse, mutect2
- ADAM22 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99715519; called by muse, mutect2, varscan2
- ADGRD1 | c.2207G>C p.R736T | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99893749; called by muse, mutect2
- AKAP5 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); catalogued as COSV100277824; called by muse, mutect2
- AKR1D1 | c.715T>G p.L239V | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99652753; called by muse, mutect2
- ANKRD13C | c.1366A>T p.S456C | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV99256107; called by muse, mutect2
- AP1G1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55497640; called by muse, mutect2
- APOL4 | c.686T>C p.V229A (on ENST00000352371 / NM_145660.2; = p.V226A on NM_030643.4) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV100274027; called by muse, mutect2
- APPBP2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs760914598, COSV99319389; called by muse, mutect2, varscan2
- ARHGAP35 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as COSV101350665; called by muse, mutect2
- ASB8 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs149438083; called by muse, mutect2
- ASTN2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57749553, COSV57783585; called by muse, mutect2, varscan2
- ASXL3 | c.2287A>G p.R763G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99323048; called by muse, mutect2
- ATE1 | c.724T>C p.F242L | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99816700; called by muse, mutect2, varscan2
- ATRNL1 | c.1533-2A>G p.X511_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | catalogued as COSV61796946; called by muse, mutect2
- ATRX | c.1373C>G p.S458* | Nonsense Mutation (SNP) | VAF 11/200 reads (6%) | catalogued as COSV100969911, COSV100971604; called by muse, mutect2
- BCHE | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100012005, COSV52253121; called by muse, mutect2
- BTBD10 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99533287; called by muse, mutect2
- C10orf90 | c.2037A>T p.R679S | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99502913; called by muse, mutect2, varscan2
- C3AR1 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99368033; called by muse, mutect2
- CA5B | c.110A>T p.Y37F | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.067); catalogued as COSV100590670; called by muse, mutect2, varscan2
- CALCR | c.816G>T p.K272N (on ENST00000649521 / NM_001164737.2; = p.K256N on NM_001742.4) | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV100810320; called by muse, mutect2
- CASD1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV99802197; called by muse, mutect2, varscan2
- CBLL1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as COSV99755371; called by muse, mutect2
- CD300LD | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100032270, COSV60083687; called by muse, mutect2, varscan2
- CENPJ | c.2380G>T p.D794Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101121444; called by muse, mutect2
- CSDE1 | c.1790A>T p.Y597F (on ENST00000358528 / NM_001007553.3; = p.Y566F on NM_007158.6) | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV99793913; called by muse, mutect2, varscan2
- CSMD2 | c.9152C>T p.T3051I | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.934); catalogued as COSV99585229; called by muse, mutect2
- CST8 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV55671173, COSV99849851; called by muse, mutect2
- CYP4F12 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 11/176 reads (6%) | catalogued as COSV100215557; called by muse, mutect2
- CYSLTR1 | c.458T>A p.L153* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100964703; called by muse, mutect2
- DAPK2 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV99976999; called by muse, mutect2
- DIP2C | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99789748; called by muse, mutect2, varscan2
- DLGAP2 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.332); catalogued as rs754214009, COSV101420996; called by muse, mutect2, varscan2
- DOCK11 | c.262G>C p.V88L | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV99352737; called by muse, mutect2
- DYDC1 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as COSV99757958; called by muse, mutect2, varscan2
- EFCAB12 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV100394435, COSV100394598; called by muse, mutect2
- EFHC2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs199652921, COSV101375488, COSV69554469; called by mutect2, varscan2
- EGR3 | c.1038C>G p.D346E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100416077; called by muse, mutect2, varscan2
- EIF2D | c.1634A>G p.Q545R | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99662495; called by muse, mutect2
- ERMN | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101263017; called by muse, mutect2
- ESPL1 | c.5320C>T p.R1774* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99228798; called by muse, mutect2, varscan2
- F8 | c.4567G>C p.D1523H | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100811220; called by muse, mutect2
- FAM117A | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV99544410; called by muse, mutect2
- FAM169A | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs780753857, COSV100998291; called by muse, mutect2, varscan2
- FLG2 | c.4667C>A p.S1556Y | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV101165569, COSV66168460; called by muse, mutect2, varscan2
- FLG2 | c.2942C>A p.S981* | Nonsense Mutation (SNP) | VAF 57/422 reads (14%) | catalogued as COSV66170410; called by muse, mutect2, varscan2
- FN1 | c.3392T>G p.V1131G | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115664; called by muse, mutect2
- GALC | c.1306A>T p.R436* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | catalogued as COSV99728878; called by muse, mutect2
- GALNT13 | c.1222A>G p.K408E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV101222020; called by muse, mutect2, varscan2
- GALR1 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV100231636; called by muse, mutect2, varscan2
- GDPD2 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100978529; called by muse, mutect2
- GPR35 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs760148943, COSV60578594; called by muse, mutect2, varscan2
- GPS2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV59747879; called by muse, mutect2, varscan2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by mutect2, varscan2
- HCRTR2 | c.1003C>A p.H335N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100904103; called by muse, mutect2
- HDX | c.875A>T p.N292I | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99946463; called by muse, mutect2
- HEPH | c.2716G>T p.G906C (on ENST00000343002; = p.G639C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100293966; called by muse, mutect2
- HIP1R | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.327); catalogued as COSV99458118; called by muse, mutect2
- HK1 | c.2476G>C p.V826L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100065262; called by muse, mutect2
- HPN | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99384795; called by muse, mutect2
- HSD17B3 | c.323C>G p.T108R | Missense Mutation (SNP) | VAF 7/223 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100931235; called by muse, mutect2
- HSD3B2 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101027402; called by muse, mutect2
- IGF2BP1 | c.684-2A>C p.X228_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99288182; called by muse, varscan2
- IGHV1-58 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs781909598; called by muse, mutect2, varscan2
- IGHV3-20 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs567278610; called by muse, mutect2, varscan2
- IL7 | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99804793; called by muse, mutect2, varscan2
- IP6K1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100389710; called by muse, mutect2, varscan2
- ITGA4 | c.2303T>C p.I768T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101223052; called by muse, mutect2, varscan2
- ITGB6 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV99324052; called by muse, mutect2, varscan2
- KAT14 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100890020; called by muse, mutect2, varscan2
- KCNJ3 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99715137; called by muse, mutect2
- KIAA1210 | c.4375A>G p.N1459D | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as COSV101273889; called by muse, mutect2
- KRT71 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99921917; called by muse, mutect2
- LAMP3 | c.74T>C p.M25T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99660282; called by muse, mutect2
- LCT | c.1370G>C p.W457S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99928415; called by muse, mutect2, varscan2
- LIMD1 | c.1868A>G p.Y623C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99836720; called by muse, mutect2, varscan2
- LMX1B | c.1181C>T p.S394F (on ENST00000373474 / NM_001174147.2; = p.S387F on NM_002316.4) | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100826828; called by muse, mutect2
- LRRK2 | c.2878A>T p.R960W | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100108925; called by muse, mutect2
- MACROD2 | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | catalogued as COSV99426122; called by muse, mutect2
- MAP3K9 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1483217886, COSV67122223; called by muse, mutect2, varscan2
- MDGA2 | c.2501A>G p.N834S (on ENST00000399232 / NM_001113498.2; = p.N536S on NM_182830.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100636226; called by muse, mutect2, varscan2
- MOCS3 | c.123A>T p.E41D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.047); catalogued as COSV99724120; called by muse, mutect2, varscan2
- MON2 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as COSV99741415; called by muse, mutect2, varscan2
- MS4A12 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99188438; called by muse, mutect2, varscan2
- MSH5 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100994641; called by muse, mutect2
- MTUS2 | c.4024A>T p.I1342F (on ENST00000612955 / NM_001366650.1; = p.I321F on NM_015233.6) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV101070751; called by muse, mutect2, varscan2
- NAV3 | c.3421C>A p.P1141T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760869929, COSV99886398; called by muse, mutect2
- NAV3 | c.3422C>A p.P1141H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99886401; called by muse, mutect2, varscan2
- NLGN4X | c.2315C>A p.P772Q | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99319599; called by muse, mutect2
- NPHS2 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 11/184 reads (6%) | catalogued as rs1469863276, CM156476, COSV100858113; called by muse, mutect2
- NSD2 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100372764; called by muse, mutect2, varscan2
- NUMA1 | c.6106C>T p.P2036S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1262339176, COSV99474448; called by muse, mutect2
- NUP210L | c.1396A>T p.M466L | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99667072; called by muse, mutect2
- NXPE4 | c.158T>C p.L53S | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100970286; called by muse, mutect2
- NYAP2 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs1377679283, COSV56020032; called by muse, mutect2
- NYNRIN | c.5498T>G p.L1833R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV101230482; called by muse, mutect2
- OR10J1 | c.753C>A p.Y251* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV101419773; called by muse, mutect2, varscan2
- OR12D2 | c.347T>C p.M116T | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011077; called by muse, mutect2
- OR2AK2 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100823042; called by muse, mutect2, varscan2
- OR2M7 | c.118A>T p.M40L | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV100522399; called by muse, mutect2
- OR2T1 | c.884A>T p.D295V | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs879782523, COSV100822243; called by muse, mutect2, varscan2
- OR2T6 | c.790T>C p.S264P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100861471; called by muse, mutect2
- OR4F15 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 179/403 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV100173808; called by muse, mutect2, varscan2
- OR5K1 | c.473T>A p.I158N | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100220852; called by muse, mutect2
- OR9Q2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs777177506, COSV61112379; called by muse, mutect2
- PAGE4 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV99489759, COSV99489790; called by muse, mutect2, varscan2
- PARP8 | c.1376C>G p.S459* | Nonsense Mutation (SNP) | VAF 5/82 reads (6%) | catalogued as COSV99889828; called by muse, mutect2
- PDE10A | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV100604258; called by muse, mutect2
- PDHA1 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.846); catalogued as CM961095, COSV100870194; called by muse, mutect2, varscan2
- PLXNA4 | c.2798G>A p.C933Y | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100322138; called by muse, mutect2
- POM121L12 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs778644787, COSV101374829; called by muse, mutect2, varscan2
- PPM1E | c.1312T>A p.Y438N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100375648; called by muse, mutect2, varscan2
- PRELID2 | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.779); catalogued as COSV100596976; called by muse, mutect2, varscan2
- PRG2 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.307); catalogued as COSV100314835; called by muse, mutect2
- RADX | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV100998725, COSV100998820; called by muse, mutect2
- RC3H1 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV51197740; called by muse, mutect2
- RELN | c.6106G>A p.A2036T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs371614773; ClinVar: uncertain significance; called by muse, mutect2
- RPN1 | c.1095A>G p.I365M | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV99956828; called by muse, mutect2, varscan2
- RSPO2 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | catalogued as COSV52640252; called by muse, mutect2
- RTL9 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV101511613; called by muse, mutect2
- SAGE1 | c.914T>C p.M305T | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV100186552; called by muse, mutect2, varscan2
- SAMD9L | c.2520G>A p.M840I | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.436); catalogued as COSV100560248; called by muse, mutect2
- SAP130 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.964); catalogued as rs898219205, COSV99384033; called by muse, mutect2
- SCN11A | c.2816A>G p.Q939R | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100180780; called by muse, mutect2
- SECISBP2L | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55937932, COSV99959777; called by muse, mutect2
- SEL1L2 | c.1251C>G p.Y417* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99532465; called by muse, varscan2
- SETD1A | c.3859G>C p.E1287Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV99352295; called by muse, mutect2, varscan2
- SHTN1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as COSV99598399; called by muse, mutect2
- SI | c.4214C>A p.T1405K | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100013644; called by muse, mutect2, varscan2
- SLC35D3 | c.738C>A p.C246* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100090373; called by muse, mutect2, varscan2
- SLC44A3 | c.1537G>A p.D513N (on ENST00000271227 / NM_001114106.3; = p.D465N on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99597746; called by muse, mutect2
- SLC7A7 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1444757846, COSV99591503; called by muse, mutect2
- SLCO6A1 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV65806559; called by muse, mutect2, varscan2
- SLITRK2 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs782066743, COSV100157286; called by muse, mutect2, varscan2
- SMC1A | c.2028G>C p.E676D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV100446969, COSV59130965; called by muse, mutect2, varscan2
- SNX13 | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as COSV101296773; called by muse, mutect2, varscan2
- SNX16 | c.512G>C p.W171S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100629461, COSV62034035; called by muse, mutect2
- SPRR2F | c.187T>A p.C63S | Missense Mutation (SNP) | VAF 30/502 reads (6%) | PolyPhen benign (0.021); catalogued as COSV100907507; called by muse, mutect2
- SPTA1 | c.3980T>A p.L1327* | Nonsense Mutation (SNP) | VAF 9/202 reads (4%) | catalogued as COSV100934107; called by muse, mutect2
- SUPT6H | c.3148A>G p.I1050V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1211853753, COSV100112026; called by muse, mutect2
- SYDE2 | c.1889C>G p.T630R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756769472, COSV99320163; called by muse, mutect2, varscan2
- SYNM | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs782165312, COSV100152353; called by muse, mutect2
- SYT12 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV101210802; called by muse, mutect2
- TENM1 | c.3136C>A p.H1046N | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100948891; called by muse, mutect2, varscan2
- TET2 | c.1489A>T p.T497S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs972594430, COSV54412504, COSV54412770; called by muse, mutect2, varscan2
- TMEM132B | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV100168293; called by muse, mutect2, varscan2
- TRIM51 | c.1045del p.D349Tfs*23 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as rs753441659, COSV99793186; called by mutect2, pindel, varscan2
- TSR2 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV100910756; called by muse, mutect2, varscan2
- TTC5 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99351499; called by muse, mutect2, varscan2
- VWC2 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61485197, COSV61492375; called by muse, mutect2
- WNT16 | c.1008C>A p.H336Q (on ENST00000222462 / NM_057168.2; = p.H326Q on NM_016087.2) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV99742882; called by muse, mutect2, varscan2
- XIAP | c.1327C>G p.R443G | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV100848809, COSV63024795; called by muse, mutect2
- ZBTB11 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100465042; called by muse, mutect2, varscan2
- ZFAT | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100914139; called by muse, mutect2
- ZIC4 | c.836G>C p.S279T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101267795; called by muse, mutect2, varscan2
- ZNF154 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101377439; called by muse, mutect2
- CLDN2 | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- CNDP1 | c.1255A>T p.I419F | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2
- COL2A1 | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRAS1 | c.10535G>A p.R3512K | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGHV3-53 | c.9T>A p.F3L | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV6-21 | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- PKP4 | c.1170dup p.A391Cfs*2 | Frame Shift Ins (INS) | VAF 19/168 reads (11%) | called by mutect2, pindel, varscan2
- ACTL6A | c.174C>T p.G58= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs768320763, COSV101199600; called by muse, mutect2, varscan2
- AMMECR1 | c.42C>T p.S14= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1207437288, COSV99466183; called by muse, mutect2, varscan2
- APOB | c.2721C>T p.H907= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs72653068, COSV99263243; called by muse, mutect2, varscan2
- ARHGAP17 | c.354G>A p.E118= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as COSV99252791; called by muse, mutect2
- ASNS | c.1212C>T p.R404= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs771358131, COSV51557027; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP12A | c.2316C>T p.S772= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1427247901, COSV99516896; called by muse, mutect2, varscan2
- BTAF1 | c.18A>G p.L6= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99794793; called by muse, mutect2, varscan2
- C1orf74 | c.807C>G p.L269= | Silent (SNP) | VAF 13/225 reads (6%) | catalogued as COSV99159998; called by muse, mutect2
- CCDC50 | c.498A>G p.R166= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV101165235; called by muse, mutect2
- CCDC65 | c.759G>A p.K253= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99872655; called by muse, mutect2
- CLEC14A | c.651G>T p.R217= | Silent (SNP) | VAF 30/244 reads (12%) | catalogued as COSV100643476; called by muse, mutect2, varscan2
- DNAH5 | c.8664G>A p.E2888= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs762931958, COSV99444200; called by mutect2, varscan2
- DUSP26 | c.372T>C p.F124= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99823304; called by muse, mutect2, varscan2
- FAM163A | c.426C>T p.P142= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV100522848, COSV59203552; called by muse, mutect2, varscan2
- FRMPD2 | c.477G>A p.R159= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100563445; called by muse, mutect2
- GABRQ | c.1692G>A p.E564= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100941073, COSV64782092; called by muse, mutect2, varscan2
- GLUD2 | c.33G>T p.P11= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV60152791; called by muse, mutect2, varscan2
- HCFC1 | c.153C>A p.G51= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100128309; called by muse, mutect2, varscan2
- IL2RA | c.273G>A p.T91= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs41290331, COSV56923445; called by muse, mutect2
- IQCB1 | c.129C>T p.S43= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100181512; called by muse, mutect2, varscan2
- KCTD16 | c.1035C>T p.P345= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV101568700, COSV72580931; called by muse, mutect2, varscan2
- MMS22L | c.2862A>G p.A954= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs1029078855, COSV99245978; called by muse, mutect2, varscan2
- MS4A5 | c.567C>T p.C189= | Silent (SNP) | VAF 8/189 reads (4%) | catalogued as COSV55740410; called by muse, mutect2
- MTA1 | c.162C>T p.T54= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV100494868; called by muse, mutect2
- MTUS2 | c.4023G>C p.P1341= (on ENST00000612955 / NM_001366650.1; = p.P320= on NM_015233.6) | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV101070750, COSV66420144; called by muse, mutect2, varscan2
- NEURL1 | c.1593G>A p.T531= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs754801374, COSV100582927, COSV100583504; called by muse, mutect2, varscan2
- OR4L1 | c.615G>C p.L205= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV100235541; called by muse, mutect2
- OR5AS1 | c.597C>G p.L199= | Silent (SNP) | VAF 29/414 reads (7%) | catalogued as rs375389223, COSV100546145; called by muse, mutect2
- PCF11 | c.111C>T p.I37= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV53534018, COSV53537612; called by muse, mutect2
- POP1 | c.2253A>G p.K751= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100855612; called by muse, mutect2, varscan2
- RBM28 | c.1287G>T p.T429= | Silent (SNP) | VAF 26/322 reads (8%) | catalogued as COSV56162591, COSV99775444; called by muse, mutect2
- RYR2 | c.5094G>A p.L1698= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100767369; called by muse, mutect2, varscan2
- SMARCA1 | c.3121C>A p.R1041= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100946304; called by muse, mutect2, varscan2
- SOGA3 | c.2292C>T p.D764= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100846743; called by muse, mutect2, varscan2
- SPAG17 | c.3633T>A p.P1211= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100307677; called by muse, mutect2, varscan2
- SPIN2B | c.678C>G p.G226= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as COSV99328109; called by muse, mutect2, varscan2
- SYNE1 | c.3330T>G p.A1110= (on ENST00000367255 / NM_182961.4; = p.A1117= on NM_033071.3) | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV99551271; called by muse, mutect2
- TAS2R46 | c.333C>A p.A111= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV101113982; called by muse, varscan2
- TP53TG5 | c.732C>T p.S244= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs1325543101, COSV101022294; called by muse, mutect2, varscan2
- TRGC1 | c.18A>G p.A6= | Silent (SNP) | VAF 32/289 reads (11%) | catalogued as rs770240313; called by muse, mutect2, varscan2
- TSPAN3 | c.168G>T p.V56= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV99144407; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1260A>G p.T420= | Silent (SNP) | VAF 21/215 reads (10%) | catalogued as rs750908464, COSV99691016; called by muse, mutect2, varscan2
- USF3 | c.1875A>G p.P625= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100324658; called by muse, mutect2, varscan2
- EPHA10 | c.850+11G>T | Intron (SNP) | VAF 13/194 reads (7%) | catalogued as COSV100139684; called by muse, mutect2
- OR3A4P | n.1269G>T | RNA (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
